TCGA case TCGA-06-0206 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Henry Ford Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4d04939f-9509-4e9b-9406-16051afecf82

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 40 years; Vital status: Dead; Days to death: 233 days.

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 40.9 years (14,937 days); Year of diagnosis: 1996; Method of diagnosis: Surgical Resection; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 18 days; Days to treatment end: 79 days; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carmustine; Treatment intent type: Adjuvant; Days to treatment start: 138 days; Days to treatment end: 138 days; Number of cycles: 1; Prescribed dose: 200; Prescribed dose units: mg; Route of administration: Intravenous.
2. Recurrence of diagnosis 1 (Glioblastoma). Age at diagnosis: 41.2 years (15,043 days); Days to diagnosis: 106 days; Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for recurrent disease; Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 106 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 106 days.
- Days to follow up: 197 days; Disease response: With Tumor.
- Days to follow up: 233 days; Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-06-0206-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
  Slide TCGA-06-0206-01A-01-TS1: Section location: Top; Percent tumor cells: 88; Percent tumor nuclei: 98; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 2.
  Slide TCGA-06-0206-01A-01-BS1: Section location: Bottom; Percent tumor cells: 100; Percent tumor nuclei: 98; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-06-0206-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-06-0206-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Method initial path diagnosis: Tumor resection.
- Drug treatment: Pharmaceutical therapy drug name: Carmustine (BCNU).
- Drug treatment, Route of administrations: Route of administration: IV.
- Radiation treatment: Therapy regimen other: No other information available in medical record.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 233 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 233 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 106 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-06-0206-01): tumor purity 0.62, ploidy 2.05, whole-genome doublings 0 (call status: legacy_call).
